Surgical pathology report (de-identified scan), TCGA case TCGA-CR-5250, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-5250-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

DIAGNOSIS:

1) TONGUE, RIGHT BASE, BIOPSY: POORLY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA (SEE COMMENT).

COMMENT: Immunohistochemical studies show strong marking with p16, and HPV is negative.

* [REDACTED]

[REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

[REDACTED]

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) right base of tongue

INSTRUCTIONS: High-risk HPV ISH P16 IHC.

GROSS DESCRIPTION:

1) SOURCE: Right Base of Tongue. Received fresh labeled "right base of tongue," is one larger fragment and multiple minute fragments of pink-tan to red tissue measuring in aggregate 8.0 x 6.0 x 4.0 mm. The largest portion of tissue has a white, thickened, polypoid surface. The section margin of this larger portion is inked black. The specimen is submitted entirely. Tissue is submitted for future possible study.

Summary of sections: 1A, larger portion, 2/1; 1B, fragments in a tissue bag, M/1.

[REDACTED]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report

[REDACTED]

[page 2 of 2]
above: 1xP16, 1xPAPILLOMA VIRUS

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

The following report contains additional information regarding HPV studies that supplements the previously issued report.

ADDENDUM FINDINGS: HPV analyses as performed by [REDACTED]
Laboratories show the tumor to be p16 positive by immunohistochemistry and HPV-16 positive by in situ

[REDACTED]
[REDACTED]
[REDACTED]
Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file 6c8aaba6-464d-4014-b318-ef55b2f356d7 (TCGA-CR-5250.E9150C7C-62F9-4903-9D00-B6EF6B24166A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).